Somatic mutation profile of tumor specimen TCGA-D1-A17M-01A (aliquot TCGA-D1-A17M-01A-21D-A12J-09) from TCGA case TCGA-D1-A17M, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G1; Age at diagnosis: 56.6 years (20,685 days).
Specimen TCGA-D1-A17M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4661edcf-c964-4ae4-910d-7d3a55686e45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A17M-10A (Blood Derived Normal), aliquot TCGA-D1-A17M-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb74ebc6-6102-477d-9251-4ce990dfb877

The open-access MAF lists 502 somatic variants for this specimen: 388 protein-altering or splice-affecting, 105 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 269, Silent 105, Frame Shift Del 78, Nonsense Mutation 18, Frame Shift Ins 14, Splice Site 5, RNA 5, In Frame Del 3, Intron 2, 3'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADVL | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369560930, CM990084; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CHD7 | c.2572C>T p.R858* | Nonsense Mutation (SNP) | VAF 92/397 reads (23%) | catalogued as rs1563625351, CM060900, COSV71110969; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 24/172 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, varscan2
- CTNNB1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 32/175 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 78/282 reads (28%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 115/292 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 72/310 reads (23%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- AASS | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 66/261 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as rs775343129, COSV62791507; called by muse, mutect2, varscan2
- ABCA1 | c.6532del p.Y2178Tfs*26 | Frame Shift Del (DEL) | VAF 194/512 reads (38%) | catalogued as CM075933, COSV66069911; called by mutect2, pindel, varscan2
- ABCA1 | c.4823T>C p.V1608A | Missense Mutation (SNP) | VAF 10/328 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV66069916; called by muse, mutect2
- ABCA13 | c.8111G>A p.G2704D | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV101447191, COSV71293398; called by muse, mutect2, varscan2
- ABCC1 | c.458T>C p.L153P | Missense Mutation (SNP) | VAF 60/307 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV60692923; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 16/96 reads (17%) | catalogued as rs749943218; called by mutect2, varscan2
- AC013489.1 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs762523583, COSV51550593; called by muse, varscan2
- AC013489.1 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs778994249, COSV51553273; called by muse, varscan2
- ACAD11 | c.1138C>T p.Q380* | Nonsense Mutation (SNP) | VAF 206/536 reads (38%) | catalogued as COSV53900703; called by muse, mutect2, varscan2
- ACOX3 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs528832606, COSV62710694; called by muse, mutect2, varscan2
- ACSBG1 | c.437C>A p.A146D | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51909980; called by muse, mutect2, varscan2
- ACTA2 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 126/732 reads (17%) | catalogued as COSV56517911; called by muse, mutect2, varscan2
- ACTRT1 | c.708G>T p.E236D | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV64419932; called by muse, mutect2, varscan2
- ADAMTS19 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 43/287 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV50790071; called by muse, mutect2, varscan2
- ADAP2 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.46); catalogued as COSV58295988; called by muse, mutect2, varscan2
- ADGRG5 | c.608del p.G203Afs*62 | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | catalogued as rs750862917; called by mutect2, pindel, varscan2
- ADRA1A | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52372439; called by muse, mutect2, varscan2
- AKAP17A | c.1546G>A p.V516M | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.055); catalogued as rs140581976, COSV58311697; called by muse, mutect2, varscan2
- ALDH2 | c.864del p.K289Rfs*122 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | catalogued as rs771889973, COSV55672572; called by mutect2, pindel, varscan2
- ALOX15 | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.56); catalogued as rs143347429; called by muse, mutect2, varscan2
- AMER3 | c.611del p.P204Rfs*62 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as COSV100365971, COSV58465768; called by mutect2, pindel, varscan2
- AMER3 | c.1138G>A p.V380M | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); catalogued as rs781067603, COSV58469562; called by muse, mutect2, varscan2
- ANXA9 | c.216C>A p.S72R | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as COSV64485485; called by muse, mutect2
- APC | c.2566C>G p.R856G | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.819); catalogued as COSV57348747, COSV57376259; called by muse, mutect2, varscan2
- APOB | c.7823A>G p.Q2608R | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.037); catalogued as rs767180578, COSV51949795; called by muse, mutect2, varscan2
- AQP6 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs766657221, COSV59646258; called by muse, mutect2, varscan2
- AR | c.554T>C p.L185P | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65963188, COSV65963361; called by muse, mutect2, varscan2
- ARAP3 | c.3134C>T p.A1045V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs368544318; called by muse, mutect2, varscan2
- ARCN1 | c.1027C>G p.L343V | Missense Mutation (SNP) | VAF 31/270 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50617111; called by muse, mutect2, varscan2
- ASH1L | c.4477C>T p.R1493C | Missense Mutation (SNP) | VAF 137/675 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs747263928, COSV64212875; called by muse, mutect2, varscan2
- ATG101 | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 71/244 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.014); catalogued as rs1199689526, COSV61085000; called by muse, mutect2, varscan2
- ATOH8 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs754920791, COSV60400023; called by muse, mutect2, varscan2
- ATP6V1A | c.143G>T p.S48I | Missense Mutation (SNP) | VAF 78/484 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as COSV56364244; called by muse, varscan2
- ATP6V1C2 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 91/516 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758292790, COSV55362308; called by muse, mutect2, varscan2
- ATRN | c.1078A>G p.M360V | Missense Mutation (SNP) | VAF 194/478 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs145181041; called by muse, mutect2, varscan2
- B3GALNT1 | c.314del p.K105Sfs*14 | Frame Shift Del (DEL) | VAF 49/317 reads (15%) | catalogued as rs759975633; called by mutect2, pindel, varscan2
- B3GAT3 | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.058); catalogued as COSV55490335; called by muse, mutect2, varscan2
- BFAR | c.272T>C p.I91T | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV55494337; called by muse, mutect2, varscan2
- BRAF | c.1328del p.P443Lfs*8 (on ENST00000288602 / NM_001374244.1; = p.P403Lfs*8 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 37/258 reads (14%) | catalogued as COSV56263190; called by mutect2, pindel, varscan2
- BRAT1 | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs755296109, COSV61396051; called by muse, mutect2, varscan2
- BRCA2 | c.4534C>T p.R1512C | Missense Mutation (SNP) | VAF 66/128 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs80358684, COSV66461184; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- BRPF3 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1160592236, COSV60207201; called by muse, mutect2
- BUB3 | c.821G>T p.R274L | Missense Mutation (SNP) | VAF 63/379 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV64364173; called by muse, mutect2, varscan2
- C1orf141 | c.970C>A p.L324I | Missense Mutation (SNP) | VAF 75/335 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV63993261; called by muse, mutect2, varscan2
- C6 | c.1049A>C p.N350T | Missense Mutation (SNP) | VAF 171/390 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54716970; called by muse, mutect2, varscan2
- C8orf74 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs199982496, COSV58755404; called by muse, mutect2, varscan2
- C9orf135 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768524639, COSV65876386; called by muse, mutect2, varscan2
- CAMKK2 | c.314C>A p.S105Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as COSV61217368; called by muse, varscan2
- CAPN10 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV54379338; called by muse, mutect2, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 107/453 reads (24%) | catalogued as rs765105588; called by mutect2, varscan2
- CBX2 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53968547; called by muse, mutect2, varscan2
- CCDC106 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV58272641; called by muse, mutect2, varscan2
- CCDC121 | c.91C>A p.L31I | Missense Mutation (SNP) | VAF 67/441 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.169); catalogued as COSV53117288; called by muse, mutect2, varscan2
- CD44 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 40/296 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV53531114; called by muse, mutect2, varscan2
- CDH10 | c.803G>T p.R268L | Missense Mutation (SNP) | VAF 126/312 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV52594580; called by muse, mutect2, varscan2
- CDH20 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 69/247 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.099); catalogued as rs751531893, COSV53004584; called by muse, mutect2, varscan2
- CDH26 | c.1655G>T p.G552V | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV54853315; called by muse, mutect2, varscan2
- CDK17 | c.1216G>T p.G406* | Nonsense Mutation (SNP) | VAF 35/261 reads (13%) | catalogued as rs1253898393, COSV54132943; called by muse, mutect2, varscan2
- CEP112 | c.1073del p.K358Sfs*6 | Frame Shift Del (DEL) | VAF 108/731 reads (15%) | catalogued as rs769310263; called by mutect2, pindel, varscan2
- CEP128 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 78/619 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53677830; called by muse, mutect2, varscan2
- CIAO1 | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 52/286 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.333); catalogued as COSV51498845; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 27/122 reads (22%) | catalogued as rs752250702; called by mutect2, varscan2
- CLEC2D | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV51995592; called by muse, mutect2, varscan2
- CLUH | c.2768G>T p.G923V (on ENST00000435359; = p.G962V on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as COSV70929934; called by muse, mutect2, varscan2
- CMKLR1 | c.730G>A p.V244M (on ENST00000312143 / NM_001142344.2; = p.V242M on NM_004072.3) | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs761623535, COSV56436189; called by muse, mutect2, varscan2
- CMYA5 | c.6720G>T p.E2240D | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV71409076; called by muse, mutect2, varscan2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 54/289 reads (19%) | catalogued as rs761011518, COSV99078405; called by mutect2, pindel, varscan2
- COG5 | c.1357G>C p.A453P | Missense Mutation (SNP) | VAF 60/528 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV51762234; called by muse, mutect2, varscan2
- COL13A1 | c.1828G>T p.G610C (on ENST00000398978 / NM_001130103.2; = p.G538C on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62574288; called by muse, mutect2, varscan2
- COL4A4 | c.4766C>T p.P1589L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768974023, COSV61635908; called by muse, mutect2, varscan2
- CRNN | c.549A>G p.I183M | Missense Mutation (SNP) | VAF 54/598 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.254); catalogued as COSV55123565; called by muse, mutect2
- CRYBG2 | c.4262C>T p.A1421V | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57489387; called by muse, mutect2, varscan2
- CSMD3 | c.10868C>T p.P3623L (on ENST00000297405 / NM_001363185.1; = p.P3454L on NM_052900.3) | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.109); catalogued as COSV52296496; called by muse, mutect2, varscan2
- CSMD3 | c.6610G>T p.D2204Y (on ENST00000297405 / NM_001363185.1; = p.D2100Y on NM_052900.3) | Missense Mutation (SNP) | VAF 69/526 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52107005; called by muse, mutect2, varscan2
- CSMD3 | c.1819G>A p.D607N (on ENST00000297405 / NM_001363185.1; = p.D503N on NM_052900.3) | Missense Mutation (SNP) | VAF 38/320 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs766999292, COSV52296542, COSV52298491, COSV99033695; called by muse, mutect2, varscan2
- CTNNBL1 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 134/580 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs745535538, COSV63746512; called by muse, mutect2, varscan2
- CUL9 | c.947G>A p.S316N | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1057252064, COSV52733775; called by muse, mutect2, varscan2
- CYP24A1 | c.743C>T p.T248M | Missense Mutation (SNP) | VAF 172/406 reads (42%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.559); catalogued as rs16999131, CM138517, COSV53775139; called by muse, mutect2, varscan2
- CYP2B6 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 92/374 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs752695347, COSV57844965; called by muse, mutect2, varscan2
- DCAF15 | c.228A>G p.A76= | Splice Region (SNP) | VAF 11/48 reads (23%) | catalogued as COSV54335092, COSV54337598; called by muse, mutect2, varscan2
- DDX39A | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs753497125, COSV54393153, COSV99660081; called by muse, mutect2, varscan2
- DDX42 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs767661453, COSV63791187; called by muse, mutect2
- DENND2A | c.1152G>T p.E384D | Missense Mutation (SNP) | VAF 81/347 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV52057756; called by muse, mutect2, varscan2
- DGKG | c.35A>G p.E12G | Missense Mutation (SNP) | VAF 62/435 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV53971475; called by muse, mutect2, varscan2
- DHX30 | c.3380G>A p.R1127Q (on ENST00000445061 / NM_138615.3; = p.R1088Q on NM_014966.3) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.106); catalogued as rs865805465, COSV53141947; called by muse, mutect2, varscan2
- DHX35 | c.1874G>T p.G625V | Missense Mutation (SNP) | VAF 47/331 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52673776; called by muse, mutect2, varscan2
- DISP1 | c.2287C>T p.R763C | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759714329, COSV52658475; called by muse, mutect2, varscan2
- DNAH1 | c.6996G>T p.K2332N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV70226909; called by muse, mutect2, varscan2
- DNAH8 | c.3389G>A p.R1130H | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs780654058, COSV100545832, COSV59443444; called by muse, mutect2, varscan2
- DOCK11 | c.2855dup p.L952Ffs*15 | Frame Shift Ins (INS) | VAF 30/159 reads (19%) | catalogued as rs749353751; called by mutect2, pindel, varscan2
- DOCK7 | c.4924-2A>G p.X1642_splice (on ENST00000635253 / NM_001367561.1; = p.X1611_splice on NM_033407.3) | Splice Site (SNP) | VAF 59/291 reads (20%) | catalogued as COSV52019180; called by muse, mutect2, varscan2
- DOLPP1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs370550987; called by muse, mutect2, varscan2
- DOP1A | c.4712A>G p.E1571G | Missense Mutation (SNP) | VAF 38/231 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.272); catalogued as COSV52716759; called by muse, mutect2, varscan2
- DPP8 | c.493G>A p.G165R (on ENST00000341861 / NM_001320875.2; = p.G149R on NM_017743.6) | Missense Mutation (SNP) | VAF 73/551 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as rs1432951432, COSV55681000; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.024); catalogued as rs374894345; called by muse, mutect2, varscan2
- EFCAB12 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs374145594; called by muse, mutect2, varscan2
- EFCAB6 | c.1969C>T p.H657Y | Missense Mutation (SNP) | VAF 147/586 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.124); catalogued as COSV53071214; called by muse, mutect2, varscan2
- EHF | c.168G>A p.W56* | Nonsense Mutation (SNP) | VAF 20/96 reads (21%) | catalogued as COSV57669721; called by muse, mutect2, varscan2
- EMILIN3 | c.1380del p.W461Gfs*21 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | catalogued as rs759858342; called by mutect2, pindel, varscan2
- ENPP3 | c.1274G>A p.R425K | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as COSV62953443, COSV62956254; called by muse, mutect2, varscan2
- ENTPD6 | c.372dup p.R125Qfs*23 | Frame Shift Ins (INS) | VAF 5/19 reads (26%) | catalogued as rs769657862; called by mutect2, varscan2
- ENTR1 | c.653C>T p.P218L (on ENST00000357365 / NM_001039707.2; = p.P195L on NM_006643.4) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.245); catalogued as rs1052773037, COSV53743030; called by muse, mutect2, varscan2
- ERCC8 | c.53T>C p.L18P | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54017839; called by muse, mutect2, varscan2
- ETV3 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 66/431 reads (15%) | catalogued as COSV58748491; called by muse, varscan2
- FAM107A | c.48G>T p.M16I | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV62981222; called by muse, mutect2
- FAM120B | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV53007709; called by muse, mutect2
- FAM122C | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV66196229; called by muse, mutect2, varscan2
- FAM47B | c.1768A>T p.I590F | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61453253; called by muse, mutect2, varscan2
- FAM83F | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.058); catalogued as rs879539429, COSV61001162; called by muse, mutect2, varscan2
- FAT1 | c.8089G>T p.E2697* | Nonsense Mutation (SNP) | VAF 85/180 reads (47%) | catalogued as COSV71672322; called by muse, mutect2, varscan2
- FAXDC2 | c.689T>C p.M230T | Missense Mutation (SNP) | VAF 116/392 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV58173818; called by muse, mutect2, varscan2
- FBXL16 | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV50203259, COSV99556410; called by muse, mutect2, varscan2
- FBXL4 | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs763115531, COSV57749280; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGD2 | c.1326G>T p.E442D | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as COSV51465732; called by muse, mutect2, varscan2
- FGD3 | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1327827982, COSV61597712; called by muse, mutect2, varscan2
- FNBP4 | c.692A>G p.Y231C | Missense Mutation (SNP) | VAF 74/312 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55451692; called by muse, varscan2
- FOXP4 | c.450_457del p.Q150Hfs*163 (on ENST00000307972 / NM_001012426.1; = p.Q150Hfs*162 on NM_138457.3) | Frame Shift Del (DEL) | VAF 17/39 reads (44%) | catalogued as COSV57223390; called by mutect2, pindel, varscan2
- FTMT | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as rs796443362, COSV58421147; called by muse, mutect2
- FUT4 | c.1251G>T p.Q417H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV100708102, COSV62470079; called by mutect2, varscan2
- FYB2 | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 60/363 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV58588531; called by muse, mutect2, varscan2
- FZD9 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60671265; called by muse, mutect2, varscan2
- GALNT5 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.083); catalogued as rs1226497432, COSV52040661; called by muse, mutect2, varscan2
- GCKR | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs1463773205, COSV53022501; called by muse, mutect2
- GEM | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs777960854, COSV52598899; called by muse, mutect2, varscan2
- GGA2 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1352861234, COSV59167693; called by muse, mutect2, varscan2
- GIMAP8 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.192); catalogued as COSV56233431; called by muse, mutect2, varscan2
- GLI1 | c.2283T>G p.Y761* | Nonsense Mutation (SNP) | VAF 20/39 reads (51%) | catalogued as COSV57366426; called by muse, mutect2, varscan2
- GOLGB1 | c.9251G>A p.G3084D | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV61470194; called by muse, mutect2, varscan2
- GOLGB1 | c.498G>T p.Q166H | Missense Mutation (SNP) | VAF 38/866 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV61470201; called by muse, mutect2
- GORASP2 | c.928G>C p.A310P | Missense Mutation (SNP) | VAF 111/311 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as COSV52203609; called by muse, mutect2, varscan2
- GPT | c.1419del p.L474Wfs*11 | Frame Shift Del (DEL) | VAF 23/97 reads (24%) | catalogued as COSV52953289; called by mutect2, pindel, varscan2
- GRB10 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60015703; called by muse, mutect2, varscan2
- GRIA3 | c.2420G>T p.S807I | Missense Mutation (SNP) | VAF 149/322 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.123); catalogued as COSV52077906; called by muse, mutect2, varscan2
- GRM4 | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.138); catalogued as rs1473342035, COSV65212266; called by muse, mutect2
- GRM6 | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs369555190; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRM8 | c.84G>A p.M28I | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as COSV58861547; called by muse, mutect2, varscan2
- HAUS3 | c.40del p.I14Lfs*27 | Frame Shift Del (DEL) | VAF 48/284 reads (17%) | catalogued as rs748396956; called by mutect2, varscan2
- HOXC6 | c.256A>G p.N86D | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV54538043; called by muse, mutect2
- HSD17B11 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 85/379 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as rs545124516, COSV64154500; called by muse, mutect2, varscan2
- HSF1 | c.829A>G p.M277V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs370907821; called by muse, mutect2, varscan2
- HSPA2 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV55971071; called by muse, mutect2, varscan2
- HTR5A | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1204412791, COSV55280731; called by mutect2, varscan2
- IGF2R | c.3883G>A p.A1295T | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV63632260; called by muse, mutect2, varscan2
- INAVA | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.054); catalogued as rs559071760, COSV66257232, COSV66257582; called by muse, mutect2
- INPP5F | c.3199G>A p.A1067T | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.129); catalogued as rs752073299, COSV62823416; called by muse, mutect2
- INTS13 | c.1864G>A p.D622N | Missense Mutation (SNP) | VAF 82/917 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV53905089; called by muse, mutect2
- IPO11 | c.2827G>A p.A943T | Missense Mutation (SNP) | VAF 60/275 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as rs1236468159, COSV57581090; called by muse, mutect2, varscan2
- IVL | c.1431G>T p.E477D | Missense Mutation (SNP) | VAF 30/307 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.477); catalogued as COSV64216953; called by muse, mutect2
- JADE2 | c.2171G>T p.R724M | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); catalogued as COSV50929286; called by muse, mutect2, varscan2
- KALRN | c.7268C>T p.T2423I (on ENST00000360013 / NM_001024660.4; = p.T726I on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/263 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.353); catalogued as COSV52263502; called by muse, mutect2, varscan2
- KAT5 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.82); catalogued as COSV57730485; called by muse, mutect2, varscan2
- KCNJ5 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772551729, COSV57970468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM1B | c.1036G>A p.V346I (on ENST00000449850; = p.V214I on NM_153042.4) | Missense Mutation (SNP) | VAF 58/319 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs754264817, COSV52814176; called by muse, mutect2, varscan2
- KDM7A | c.298T>C p.W100R | Missense Mutation (SNP) | VAF 85/550 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV50095303; called by muse, mutect2, varscan2
- KHDC4 | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 82/521 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as COSV64165185, COSV64165625; called by muse, mutect2, varscan2
- KMT2C | c.2711G>A p.R904Q | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs764909368, COSV51493691; called by muse, mutect2, varscan2
- KRI1 | c.1301C>A p.P434H | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.206); catalogued as COSV57265770; called by muse, mutect2
- L1CAM | c.2333C>T p.T778M | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1183455686, COSV62829843; called by muse, mutect2, varscan2
- LAMB1 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as COSV55969504; called by muse, mutect2, varscan2
- LAMC1 | c.3560C>T p.A1187V | Missense Mutation (SNP) | VAF 37/240 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as rs1441990947, COSV51170772; called by muse, mutect2, varscan2
- LCAT | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.13); catalogued as rs774333955, COSV50454875; called by muse, mutect2
- LGI2 | c.1279C>T p.R427* | Nonsense Mutation (SNP) | VAF 29/111 reads (26%) | catalogued as rs759918108, COSV66122387, COSV66122923; called by muse, mutect2, varscan2
- LIG3 | c.2500G>T p.E834* | Nonsense Mutation (SNP) | VAF 11/93 reads (12%) | catalogued as COSV52009732, COSV52010510; called by muse, mutect2, varscan2
- LPAR2 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs754403177, COSV68351961; called by muse, mutect2, varscan2
- LPO | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 40/222 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); catalogued as rs746743149, COSV51860079; called by muse, mutect2, varscan2
- LRP2 | c.2540G>A p.R847H | Missense Mutation (SNP) | VAF 90/255 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs537125368, COSV55570631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LSS | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs142026899; called by muse, mutect2, varscan2
- LZIC | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1422413841, COSV65890553; called by muse, mutect2, varscan2
- MBLAC1 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs370362320; called by muse, mutect2, varscan2
- MBNL3 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63730204; called by muse, mutect2, varscan2
- MBOAT2 | c.922G>T p.G308W | Missense Mutation (SNP) | VAF 91/346 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV60011418; called by muse, mutect2, varscan2
- MC5R | c.932G>A p.C311Y | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.408); catalogued as COSV61255568; called by muse, mutect2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 68/284 reads (24%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MIDEAS | c.89del p.P30Lfs*12 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as COSV99678615; called by mutect2, pindel, varscan2
- MISP | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV53122049; called by muse, mutect2, varscan2
- MKI67 | c.4298C>T p.A1433V | Missense Mutation (SNP) | VAF 192/739 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs770946589, COSV64076468; called by muse, mutect2, varscan2
- MLPH | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368855517; called by muse, mutect2, varscan2
- MPRIP | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 122/295 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs754464266, COSV59053550; called by muse, mutect2, varscan2
- MRNIP | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 93/316 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as rs367893357; called by muse, mutect2, varscan2
- MTSS1 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs912241708, COSV52674403; called by muse, mutect2, varscan2
- MUC17 | c.3160G>A p.V1054M | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.19); catalogued as rs767490986, COSV60286634, COSV60301058; called by muse, mutect2, varscan2
- MYBPC2 | c.1946C>T p.S649L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs775056269, COSV63094393; called by muse, mutect2, varscan2
- MYBPC3 | c.1153G>A p.V385M | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772073491, CM115892, COSV57032903; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH14 | c.4517C>G p.T1506R | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.735); catalogued as COSV51829388; called by muse, mutect2, varscan2
- MYLK | c.3637G>A p.V1213M | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs368390254, CM107678; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK2 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767857271, COSV65659847; called by muse, mutect2, varscan2
- MYOM3 | c.2775del p.D926Tfs*33 | Frame Shift Del (DEL) | VAF 28/151 reads (19%) | catalogued as rs767050271; called by mutect2, pindel, varscan2
- N4BP3 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1231133291, COSV51066961; called by muse, mutect2, varscan2
- NAV1 | c.3632del p.K1211Rfs*17 | Frame Shift Del (DEL) | VAF 38/199 reads (19%) | catalogued as rs770039235; called by mutect2, varscan2
- NEB | c.11324G>A p.G3775D | Missense Mutation (SNP) | VAF 218/538 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754310164, COSV51454392; called by muse, mutect2, varscan2
- NF1 | c.7850C>T p.A2617V (on ENST00000358273 / NM_001042492.3; = p.A2596V on NM_000267.3) | Missense Mutation (SNP) | VAF 63/317 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.391); catalogued as rs375990655; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NKTR | c.2297del p.N766Ifs*30 | Frame Shift Del (DEL) | VAF 36/178 reads (20%) | catalogued as rs767007251; called by mutect2, varscan2
- NKX6-1 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1347986331, COSV55685714; called by muse, mutect2, varscan2
- NMRAL1 | c.48G>T p.Q16H | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV52061063; called by muse, mutect2, varscan2
- NOS2 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV58226976; called by muse, mutect2, varscan2
- NPC1 | c.208A>G p.N70D | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52583011; called by muse, mutect2, varscan2
- NR2F1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs748864451, COSV59069829; called by muse, mutect2, varscan2
- NR2F6 | c.281C>A p.S94Y | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52242923, COSV52245258; called by muse, mutect2, varscan2
- NSD1 | c.5617A>G p.I1873V | Missense Mutation (SNP) | VAF 122/268 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV61783488; called by muse, mutect2, varscan2
- NSDHL | c.108G>T p.Q36H | Missense Mutation (SNP) | VAF 45/257 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV64745033; called by muse, mutect2, varscan2
- NSUN5 | c.647G>A p.C216Y | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554541573, COSV53093520; called by muse, mutect2, varscan2
- NTAN1 | c.825A>T p.L275F | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs553166241, COSV55073781, COSV55075764; called by muse, mutect2, varscan2
- NUP214 | c.681del p.V228Sfs*29 | Frame Shift Del (DEL) | VAF 111/754 reads (15%) | catalogued as rs771913112, COSV63912486; called by mutect2, varscan2
- NXPE4 | c.366G>T p.E122D | Missense Mutation (SNP) | VAF 114/799 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.07); catalogued as COSV64944317; called by muse, mutect2, varscan2
- OBSCN | c.13138G>A p.V4380M | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs540010437, COSV52820665; called by muse, mutect2, varscan2
- OGT | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 119/502 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as COSV65481001; called by muse, mutect2, varscan2
- OR4C6 | c.886A>G p.M296V | Missense Mutation (SNP) | VAF 56/304 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs762535076, COSV58605969; called by muse, mutect2, varscan2
- OR51Q1 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs750405873, COSV56179937; called by muse, mutect2
- PABPC1L | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.552); catalogued as rs763727369, COSV53842287; called by muse, mutect2, varscan2
- PAPPA | c.3614G>A p.C1205Y | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV60290527; called by muse, mutect2, varscan2
- PARS2 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.087); catalogued as COSV64883918; called by muse, mutect2, varscan2
- PCDHGB1 | c.2258C>T p.A753V | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV54017983; called by muse, mutect2
- PCDHGB3 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 3/7 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53921139; called by muse, mutect2
- PDGFD | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV56371640; called by muse, mutect2, varscan2
- PGBD5 | c.1114G>A p.V372M (on ENST00000525115; = p.V441M on NM_001258311.2) | Missense Mutation (SNP) | VAF 86/279 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779820889, COSV58413358; called by muse, mutect2, varscan2
- PHACTR4 | c.1939T>C p.Y647H (on ENST00000373839 / NM_001350159.2; = p.Y657H on NM_023923.4) | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1014179296, COSV65784998; called by muse, mutect2, varscan2
- PHF14 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 91/373 reads (24%) | catalogued as rs760800245, COSV68857032; called by muse, mutect2, varscan2
- PIGT | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 42/317 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.108); catalogued as COSV54128174; called by muse, mutect2, varscan2
- PIP4P1 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 114/582 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs776716699, COSV51657593; called by muse, mutect2, varscan2
- PLAA | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 54/277 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV68305509; called by muse, mutect2, varscan2
- PLEC | c.12841G>A p.V4281M (on ENST00000322810 / NM_201380.4; = p.V4171M on NM_000445.5) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs541897170, COSV59688077; called by muse, mutect2, varscan2
- PLEKHH1 | c.3999dup p.T1334Hfs*56 | Frame Shift Ins (INS) | VAF 48/288 reads (17%) | catalogued as rs761759640; called by mutect2, varscan2
- PLXNA1 | c.1516C>T p.Q506* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as COSV52531769; called by muse, mutect2, varscan2
- POGZ | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 210/1246 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1557873791, COSV55041271; called by muse, mutect2, varscan2
- POLD1 | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.061); catalogued as rs762273084, COSV70956008; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLQ | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 104/397 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771235928, COSV51753805; called by muse, mutect2, varscan2
- PORCN | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.395); catalogued as COSV58227062; called by muse, mutect2, varscan2
- PPFIA1 | c.2582del p.K861Sfs*27 | Frame Shift Del (DEL) | VAF 46/225 reads (20%) | catalogued as rs1565441217, COSV54138882; called by mutect2, pindel, varscan2
- PPIG | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 156/485 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53645626; called by muse, mutect2, varscan2
- PPL | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as rs748208822, COSV62050377; called by muse, mutect2, varscan2
- PPP1R10 | c.2765G>A p.R922H | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs377763869; called by muse, mutect2, varscan2
- PPP1R16A | c.1333del p.H445Tfs*15 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs777096925; called by mutect2, pindel, varscan2
- PRDM14 | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52574501; called by muse, mutect2, varscan2
- PRKCG | c.557T>C p.M186T | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV54732168; called by muse, mutect2, varscan2
- PRKD1 | c.295_297del p.D99del | In Frame Del (DEL) | VAF 34/308 reads (11%) | catalogued as rs771366609; called by mutect2, pindel, varscan2
- PTEN | c.823G>T p.V275L | Missense Mutation (SNP) | VAF 59/262 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as COSV64294027, COSV64304809; called by muse, varscan2
- PTPN14 | c.3298C>T p.R1100C | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs755979033, COSV65287712; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773249438, COSV52964786; called by muse, mutect2
- RAI1 | c.2639G>A p.S880N | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as COSV55398082; called by muse, mutect2
- RBFOX2 | c.1018G>A p.A340T (on ENST00000438146 / NM_001349995.2; = p.A266T on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as rs1373405959, COSV53267757; called by muse, mutect2, varscan2
- REG3G | c.26G>A p.S9N | Missense Mutation (SNP) | VAF 82/392 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.203); catalogued as rs1344166317, COSV55451335, COSV55451416; called by muse, mutect2, varscan2
- REL | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 80/421 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372213094; called by muse, mutect2, varscan2
- RHBDF2 | c.1857G>A p.M619I | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.118); catalogued as COSV51686135; called by muse, mutect2, varscan2
- RHOBTB1 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.105); catalogued as rs1355653025, COSV61959233; called by muse, mutect2, varscan2
- RHOBTB2 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52572850; called by muse, mutect2, varscan2
- RNF20 | c.1705C>T p.R569* | Nonsense Mutation (SNP) | VAF 71/530 reads (13%) | catalogued as rs535787053, COSV66661517; called by muse, mutect2, varscan2
- RNF43 | c.583-2A>T p.X195_splice | Splice Site (SNP) | VAF 55/138 reads (40%) | catalogued as COSV68460049, COSV68460372; called by muse, mutect2, varscan2
- RSAD1 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770236887, COSV51954650, COSV51957124; called by muse, mutect2, varscan2
- SBF1 | c.197T>C p.F66S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1233471028, COSV62370154; called by muse, mutect2, varscan2
- SBSPON | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs779036043, COSV52077829; called by muse, mutect2, varscan2
- SCN10A | c.5426A>G p.K1809R | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs561166361, COSV71862541; called by muse, mutect2, varscan2
- SCTR | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.08); catalogued as rs146958478; called by muse, mutect2, varscan2
- SEC16A | c.3547G>A p.A1183T | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs775854652, COSV51539121; called by muse, mutect2, varscan2
- SELENBP1 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.019); catalogued as COSV64374117; called by muse, mutect2, varscan2
- SEMA3D | c.269T>A p.I90N | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV52402683; called by muse, mutect2, varscan2
- SF3B1 | c.2719G>T p.D907Y | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59205599; called by muse, mutect2, varscan2
- SIN3B | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs751788314, COSV56136117; called by muse, mutect2, varscan2
- SIPA1L2 | c.4678G>A p.A1560T | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs768457830, COSV53398422; called by muse, mutect2, varscan2
- SLAMF7 | c.958C>T p.L320F | Missense Mutation (SNP) | VAF 74/654 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as rs1256683038, COSV63563972; called by muse, mutect2, varscan2
- SLC10A3 | c.566A>G p.E189G | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54837279; called by muse, mutect2, varscan2
- SLC12A7 | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs746333907, COSV53761804; called by muse, mutect2, varscan2
- SLC19A1 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs1466050965, COSV60757807; called by muse, mutect2
- SLC30A2 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs149723161; called by muse, mutect2
- SLC30A3 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0.183); catalogued as rs1239755156, COSV51987471; called by muse, mutect2, varscan2
- SNTN | c.196A>G p.I66V | Missense Mutation (SNP) | VAF 43/511 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59539730; called by muse, mutect2
- SORCS1 | c.2588G>A p.G863D | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53851726, COSV53877752; called by muse, mutect2, varscan2
- SPRTN | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 90/509 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763031758, COSV50478047; called by muse, mutect2, varscan2
- SRPX2 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 43/315 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs796053342, COSV65934432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SRRM5 | c.2144C>T p.A715V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771593141, COSV56194953; called by muse, mutect2, varscan2
- STAB2 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 61/243 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777349731, COSV66337840; called by muse, mutect2, varscan2
- STAB2 | c.3360A>G p.I1120M | Missense Mutation (SNP) | VAF 70/323 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.867); catalogued as COSV66345751; called by muse, mutect2, varscan2
- STK32B | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767862829, COSV51508775; called by muse, mutect2, varscan2
- STT3A | c.923T>C p.F308S | Missense Mutation (SNP) | VAF 108/425 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV67065421; called by muse, mutect2, varscan2
- SYNE1 | c.6353A>G p.Q2118R (on ENST00000367255 / NM_182961.4; = p.Q2125R on NM_033071.3) | Missense Mutation (SNP) | VAF 15/415 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV55081511; called by muse, mutect2
- TACR3 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.216); catalogued as COSV59207642; called by muse, mutect2, varscan2
- TBC1D15 | c.1370G>C p.S457T | Missense Mutation (SNP) | VAF 62/454 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59852506; called by muse, mutect2
- TBX4 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs141536152, COSV53609474; called by muse, varscan2
- TBX5 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as rs1435645809, COSV59864637, COSV59866044; called by muse, mutect2, varscan2
- TCF20 | c.5826del p.L1943Cfs*118 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | catalogued as rs756457255; called by mutect2, pindel, varscan2
- TCOF1 | c.2312G>A p.S771N (on ENST00000377797 / NM_001135243.1; = p.S694N on NM_000356.4) | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.145); catalogued as rs1269935196, COSV60353355; called by muse, mutect2, varscan2
- TCOF1 | c.2827G>A p.G943R (on ENST00000377797 / NM_001135243.1; = p.G866R on NM_000356.4) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.526); catalogued as COSV60353377; called by muse, mutect2
- TDRKH | c.1633+1G>A p.X545_splice | Splice Site (SNP) | VAF 216/813 reads (27%) | catalogued as rs1295496343, COSV58619339; called by muse, mutect2, varscan2
- TECRL | c.765C>G p.I255M | Missense Mutation (SNP) | VAF 170/361 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.255); catalogued as COSV67090063; called by muse, mutect2, varscan2
- TECTA | c.5290C>T p.P1764S | Missense Mutation (SNP) | VAF 100/676 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50789972; called by muse, mutect2, varscan2
- TIAM1 | c.4425dup p.G1476Rfs*6 | Frame Shift Ins (INS) | VAF 13/59 reads (22%) | catalogued as rs757091901; called by mutect2, pindel, varscan2
- TLN1 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 67/271 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs145146362; called by muse, mutect2, varscan2
- TMEM120B | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs374562045; called by muse, mutect2, varscan2
- TMEM139 | c.578del p.P193Lfs*26 | Frame Shift Del (DEL) | VAF 40/243 reads (16%) | catalogued as rs1351586439; called by mutect2, pindel, varscan2
- TMEM45B | c.118C>T p.H40Y | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777107704, COSV55655099; called by muse, mutect2, varscan2
- TMEM87A | c.344C>A p.S115Y | Missense Mutation (SNP) | VAF 80/658 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as COSV56199130; called by muse, varscan2
- TNRC6B | c.3790C>T p.Q1264* (on ENST00000454349 / NM_001162501.2; = p.Q1154* on NM_015088.3) | Nonsense Mutation (SNP) | VAF 85/371 reads (23%) | catalogued as COSV57306177; called by muse, varscan2
- TREH | c.1063C>T p.Q355* | Nonsense Mutation (SNP) | VAF 53/183 reads (29%) | catalogued as COSV50626269; called by muse, mutect2, varscan2
- TRIM33 | c.3016G>A p.V1006M | Missense Mutation (SNP) | VAF 57/366 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs763612749, COSV61825480; called by muse, mutect2, varscan2
- TRPC5 | c.197T>C p.M66T | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV53301456; called by muse, mutect2
- TSPO2 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV55111726; called by muse, mutect2, varscan2
- TTF1 | c.1007del p.K336Rfs*87 | Frame Shift Del (DEL) | VAF 26/170 reads (15%) | catalogued as rs772401251; called by mutect2, varscan2
- TTF1 | c.821del p.K274Sfs*149 | Frame Shift Del (DEL) | VAF 14/106 reads (13%) | catalogued as rs770528448; called by mutect2, varscan2
- TYW1 | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 66/432 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs781635486, COSV62755687; called by muse, mutect2, varscan2
- UBR4 | c.11194C>T p.R3732W | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs776505382, COSV64398009; called by muse, mutect2, varscan2
- USHBP1 | c.54+1G>A p.X18_splice | Splice Site (SNP) | VAF 20/81 reads (25%) | catalogued as rs371356472; called by muse, mutect2, varscan2
- USP33 | c.1042A>G p.M348V | Missense Mutation (SNP) | VAF 175/399 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.243); catalogued as rs372231478, COSV62471192; called by muse, mutect2, varscan2
- USP8 | c.336A>T p.R112S | Missense Mutation (SNP) | VAF 84/369 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV56168092; called by muse, mutect2, varscan2
- VPS13D | c.10556T>A p.I3519N | Missense Mutation (SNP) | VAF 63/245 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50674984; called by muse, mutect2, varscan2
- WBP11 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs1471013746, COSV53764514; called by muse, mutect2, varscan2
- WDR88 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 70/242 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs201739777, COSV100866412, COSV63452513; called by muse, mutect2
- WNK1 | c.3298C>T p.R1100W (on ENST00000315939 / NM_018979.4; = p.R853W on NM_014823.3) | Missense Mutation (SNP) | VAF 54/243 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750612826, COSV60043658; called by muse, mutect2, varscan2
- XYLT1 | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1567288581, COSV54488244; called by muse, mutect2, varscan2
- ZBED4 | c.1732G>A p.V578M | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs769106960, COSV53467901; called by muse, mutect2, varscan2
- ZBTB6 | c.1048G>T p.G350C | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65410568; called by muse, mutect2, varscan2
- ZMYM6 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.119); catalogued as rs759201841, COSV58185288; called by muse, mutect2, varscan2
- ZNF181 | c.979G>T p.G327* | Nonsense Mutation (SNP) | VAF 24/196 reads (12%) | catalogued as COSV67627241; called by muse, mutect2, varscan2
- ZNF202 | c.1358A>G p.Y453C | Missense Mutation (SNP) | VAF 12/438 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1414261696, COSV60248356; called by muse, mutect2
- ZNF34 | c.812G>T p.R271L | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs746814537, COSV58641080; called by muse, mutect2, varscan2
- ZNF512 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 309/718 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs757452769, COSV62677699; called by muse, mutect2, varscan2
- ZNF572 | c.18dup p.L7Tfs*7 | Frame Shift Ins (INS) | VAF 108/500 reads (22%) | catalogued as rs769734933; called by mutect2, varscan2
- ZNF646 | c.3452A>T p.K1151M | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV54926346; called by muse, mutect2, varscan2
- ZNF688 | c.341C>A p.P114Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.154); catalogued as COSV56300647, COSV56301838; called by muse, mutect2, varscan2
- ZNF749 | c.2136_2138del p.I713del | In Frame Del (DEL) | VAF 26/190 reads (14%) | catalogued as rs773865309; called by pindel, varscan2
- ZNF766 | c.686G>A p.G229D | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV63010192; called by muse, mutect2, varscan2
- ABCC11 | c.2049del p.K684Rfs*6 | Frame Shift Del (DEL) | VAF 29/128 reads (23%) | called by mutect2, pindel, varscan2
- ABCG2 | c.1959del p.K653Nfs*11 | Frame Shift Del (DEL) | VAF 60/246 reads (24%) | called by mutect2, pindel, varscan2
- AGL | c.609del p.K203Nfs*2 | Frame Shift Del (DEL) | VAF 125/592 reads (21%) | called by mutect2, pindel, varscan2
- APOB | c.11919del p.A3974Rfs*33 | Frame Shift Del (DEL) | VAF 73/572 reads (13%) | called by mutect2, pindel, varscan2
- ARID1A | c.3344del p.P1115Qfs*46 | Frame Shift Del (DEL) | VAF 23/129 reads (18%) | called by mutect2, pindel, varscan2
- ARID4A | c.1602dup p.Q535Tfs*5 | Frame Shift Ins (INS) | VAF 21/120 reads (18%) | called by mutect2, pindel, varscan2
- ATAD5 | c.611del p.K204Sfs*2 | Frame Shift Del (DEL) | VAF 27/123 reads (22%) | called by mutect2, pindel, varscan2
- ATP6V1H | c.736dup p.S246Ffs*13 | Frame Shift Ins (INS) | VAF 19/128 reads (15%) | called by mutect2, pindel, varscan2
- ATRX | c.2518del p.R840Efs*29 | Frame Shift Del (DEL) | VAF 103/468 reads (22%) | called by mutect2, pindel, varscan2
- ATXN2L | c.701del p.G234Vfs*33 | Frame Shift Del (DEL) | VAF 63/189 reads (33%) | called by mutect2, pindel, varscan2
- BCL11A | c.691del p.L231Cfs*15 (on ENST00000335712 / NM_001365609.1; = p.L265Cfs*15 on NM_018014.4) | Frame Shift Del (DEL) | VAF 12/75 reads (16%) | called by mutect2, pindel
- CAMK1G | c.338del p.G113Vfs*11 | Frame Shift Del (DEL) | VAF 55/304 reads (18%) | called by mutect2, pindel, varscan2
- CCDC120 | c.765del p.S256Afs*19 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, varscan2
- CCDC186 | c.2600del p.N867Ifs*4 | Frame Shift Del (DEL) | VAF 30/240 reads (13%) | called by mutect2, pindel, varscan2
- CCDC50 | c.801del p.K267Nfs*61 | Frame Shift Del (DEL) | VAF 48/294 reads (16%) | called by mutect2, pindel, varscan2
- CHD9 | c.2280del p.F760Lfs*16 | Frame Shift Del (DEL) | VAF 47/202 reads (23%) | called by mutect2, varscan2
- CNIH1 | c.394dup p.Y132Lfs*56 | Frame Shift Ins (INS) | VAF 62/370 reads (17%) | called by mutect2, varscan2
- CRYZL1 | c.989_990del p.K330Sfs*46 | Frame Shift Del (DEL) | VAF 122/567 reads (22%) | called by mutect2, pindel, varscan2
- DAPK1 | c.3822del p.Y1275Tfs*31 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- DENND1C | c.1436del p.G479Afs*3 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- DRP2 | c.2153_2154dup p.S719Tfs*32 | Frame Shift Ins (INS) | VAF 37/204 reads (18%) | called by mutect2, varscan2
- ECSIT | c.781del p.Q261Sfs*5 | Frame Shift Del (DEL) | VAF 39/151 reads (26%) | called by mutect2, pindel, varscan2
- EFHD1 | c.370del p.A124Pfs*8 | Frame Shift Del (DEL) | VAF 27/125 reads (22%) | called by mutect2, pindel, varscan2
- FRY | c.4038dup p.T1347Hfs*48 | Frame Shift Ins (INS) | VAF 12/77 reads (16%) | called by mutect2, pindel, varscan2
- GIT1 | c.1568del p.P523Lfs*17 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | called by mutect2, pindel, varscan2
- LNPEP | c.1212dup p.Q405Sfs*5 | Frame Shift Ins (INS) | VAF 60/387 reads (16%) | called by mutect2, pindel, varscan2
- LUC7L3 | c.917_918del p.R306Kfs*14 | Frame Shift Del (DEL) | VAF 50/228 reads (22%) | called by mutect2, pindel, varscan2
- LUZP4 | c.273del p.K91Nfs*16 | Frame Shift Del (DEL) | VAF 55/381 reads (14%) | called by mutect2, pindel, varscan2
- MAP3K7 | c.627del p.K209Nfs*14 | Frame Shift Del (DEL) | VAF 28/163 reads (17%) | called by pindel, varscan2
- MAPKBP1 | c.178del p.R60Dfs*4 | Frame Shift Del (DEL) | VAF 51/308 reads (17%) | called by mutect2, pindel, varscan2
- MRPS33 | c.301del p.R101Efs*55 | Frame Shift Del (DEL) | VAF 193/831 reads (23%) | called by mutect2, pindel, varscan2
- MVP | c.164del p.P55Hfs*69 | Frame Shift Del (DEL) | VAF 17/68 reads (25%) | called by mutect2, pindel, varscan2
- MYO19 | c.1751del p.P584Lfs*9 | Frame Shift Del (DEL) | VAF 17/118 reads (14%) | called by mutect2, pindel, varscan2
- NCOA3 | c.1860del p.K620Nfs*18 | Frame Shift Del (DEL) | VAF 10/111 reads (9%) | called by mutect2, pindel
- NDUFS6 | c.275del p.G92Efs*10 | Frame Shift Del (DEL) | VAF 14/135 reads (10%) | called by mutect2, pindel
- NEGR1 | c.106_107del p.Q36Efs*23 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | called by mutect2, pindel, varscan2
- NEURL4 | c.692_693del p.S231Cfs*4 | Frame Shift Del (DEL) | VAF 24/106 reads (23%) | called by pindel, varscan2
- NUAK2 | c.437_455del p.Q146Lfs*107 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | called by pindel, varscan2*
- PARP8 | c.1334del p.F445Sfs*21 | Frame Shift Del (DEL) | VAF 24/159 reads (15%) | called by mutect2, pindel, varscan2
- PCDHGB2 | c.1294del p.L432Sfs*5 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel, varscan2
- PHKA1 | c.3460dup p.I1154Nfs*7 | Frame Shift Ins (INS) | VAF 31/220 reads (14%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.502+4_502+7del p.X168_splice | Splice Site (DEL) | VAF 38/325 reads (12%) | called by mutect2, pindel, varscan2
- PPP2R5C | c.58del p.S20Vfs*9 | Frame Shift Del (DEL) | VAF 83/550 reads (15%) | called by mutect2, pindel, varscan2
- PTEN | c.170dup p.L57Ffs*6 | Frame Shift Ins (INS) | VAF 34/213 reads (16%) | called by mutect2, pindel, varscan2
- PTEN | c.867del p.V290* | Frame Shift Del (DEL) | VAF 70/426 reads (16%) | called by pindel, varscan2
- SERPINB1 | c.952del p.I318Lfs*9 | Frame Shift Del (DEL) | VAF 31/135 reads (23%) | called by mutect2, pindel, varscan2
- SI | c.2204del p.L735Cfs*12 | Frame Shift Del (DEL) | VAF 105/393 reads (27%) | called by mutect2, pindel, varscan2
- TAS2R4 | c.638del p.N213Mfs*14 | Frame Shift Del (DEL) | VAF 48/189 reads (25%) | called by mutect2, pindel, varscan2
- TBC1D9 | c.3601del p.R1201Gfs*21 | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | called by mutect2, pindel, varscan2
- TENM3 | c.2082del p.T695Rfs*81 | Frame Shift Del (DEL) | VAF 12/104 reads (12%) | called by mutect2, pindel
- THEMIS | c.258del p.F86Lfs*27 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | called by mutect2, pindel, varscan2
- TMEM119 | c.240del p.T81Pfs*7 | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- TSHZ2 | c.1377_1380del p.L460Rfs*19 | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | called by mutect2, pindel, varscan2
- TUBA4A | c.1288_1290del p.K430del | In Frame Del (DEL) | VAF 35/185 reads (19%) | called by mutect2, pindel, varscan2
- TUSC3 | c.882del p.M295Wfs*4 | Frame Shift Del (DEL) | VAF 87/408 reads (21%) | called by mutect2, pindel, varscan2
- UBR4 | c.8406del p.M2803Cfs*16 | Frame Shift Del (DEL) | VAF 26/172 reads (15%) | called by mutect2, pindel, varscan2
- USP13 | c.353del p.L118* | Frame Shift Del (DEL) | VAF 198/794 reads (25%) | called by mutect2, pindel, varscan2
- WASHC2A | c.2451C>G p.I817M | Missense Mutation (SNP) | VAF 209/610 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.7108del p.T2370Rfs*22 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | called by mutect2, varscan2
- ZNF14 | c.1279dup p.T427Nfs*12 | Frame Shift Ins (INS) | VAF 43/199 reads (22%) | called by mutect2, pindel, varscan2
- ZNF280D | c.2395del p.S799Vfs*5 | Frame Shift Del (DEL) | VAF 106/446 reads (24%) | called by mutect2, pindel, varscan2
- AAGAB | c.120T>C p.D40= | Silent (SNP) | VAF 22/312 reads (7%) | catalogued as rs751517515, COSV56018157; called by muse, mutect2
- ADGRG3 | c.369C>T p.D123= | Silent (SNP) | VAF 23/142 reads (16%) | catalogued as rs778594810, COSV59652393; called by muse, mutect2, varscan2
- ADGRV1 | c.852T>C p.V284= | Silent (SNP) | VAF 39/244 reads (16%) | catalogued as COSV67993879; called by muse, mutect2, varscan2
- AMBN | c.822C>A p.A274= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as COSV59827890; called by muse, mutect2, varscan2
- ANKRD30A | c.975T>C p.P325= (on ENST00000611781; = p.P269= on NM_052997.2) | Silent (SNP) | VAF 37/236 reads (16%) | catalogued as rs756586414, COSV64610457, COSV64619182; called by muse, varscan2
- APOA5 | c.63C>A p.T21= | Silent (SNP) | VAF 41/152 reads (27%) | catalogued as COSV57064835; called by muse, mutect2, varscan2
- ATP11C | c.3381C>T p.D1127= | Silent (SNP) | VAF 139/366 reads (38%) | catalogued as rs781247565, COSV59563899; called by muse, mutect2, varscan2
- ATP6V1B1 | c.846G>A p.Q282= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as COSV52271374; called by muse, mutect2, varscan2
- ATP6V1G3 | c.264C>T p.Y88= | Silent (SNP) | VAF 233/905 reads (26%) | catalogued as COSV55280485; called by muse, mutect2, varscan2
- BRCA2 | c.5985C>T p.N1995= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as rs374620036, COSV66454353; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- BRINP3 | c.93G>A p.A31= | Silent (SNP) | VAF 60/329 reads (18%) | catalogued as rs762331502, COSV66538668; called by muse, mutect2, varscan2
- C1orf226 | c.519C>T p.D173= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs201405103, COSV63396715; called by muse, mutect2, varscan2
- CACNA1D | c.2043G>A p.T681= (on ENST00000350061 / NM_001128840.3; = p.T701= on NM_000720.4) | Silent (SNP) | VAF 82/386 reads (21%) | catalogued as rs752255383, COSV55462531; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNA1D | c.5940G>A p.S1980= (on ENST00000350061 / NM_001128840.3; = p.S2000= on NM_000720.4) | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs767458712, COSV55462543; called by muse, mutect2, varscan2
- CADM4 | c.351G>A p.T117= | Silent (SNP) | VAF 41/266 reads (15%) | catalogued as rs1051641182, COSV55929784; called by muse, mutect2, varscan2
- CBX2 | c.411C>T p.R137= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as rs782153522, COSV53970070; called by muse, mutect2, varscan2
- CD4 | c.1233C>T p.F411= | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as COSV50595215; called by muse, mutect2, varscan2
- CDC42BPB | c.396C>T p.D132= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV63476535; called by muse, mutect2, varscan2
- CFAP74 | c.1992C>T p.D664= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as rs951658829, COSV54572989; called by muse, mutect2, varscan2
- CHST15 | c.1665G>A p.A555= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs770361113, COSV60564735; called by muse, mutect2, varscan2
- CLEC5A | c.486G>A p.A162= | Silent (SNP) | VAF 13/337 reads (4%) | catalogued as rs782338658, COSV69396915; called by muse, mutect2
- CLPSL1 | c.28C>T p.L10= | Silent (SNP) | VAF 64/502 reads (13%) | catalogued as COSV64610501; called by muse, mutect2
- CUL3 | c.843T>C p.N281= | Silent (SNP) | VAF 110/647 reads (17%) | catalogued as COSV52369517; called by muse, mutect2, varscan2
- CWC27 | c.456C>T p.D152= | Silent (SNP) | VAF 41/374 reads (11%) | catalogued as rs373443413, COSV66884137; called by muse, mutect2, varscan2
- DDX49 | c.1167C>T p.N389= | Silent (SNP) | VAF 21/141 reads (15%) | catalogued as rs1240608466, COSV55358633; called by muse, mutect2, varscan2
- DTNA | c.657G>A p.P219= | Silent (SNP) | VAF 101/420 reads (24%) | catalogued as rs140446215; called by muse, mutect2, varscan2
- DUSP16 | c.465C>T p.A155= | Silent (SNP) | VAF 36/353 reads (10%) | catalogued as COSV53809561; called by muse, mutect2, varscan2
- DYNC1H1 | c.8172A>G p.S2724= | Silent (SNP) | VAF 28/204 reads (14%) | catalogued as COSV64141623; called by muse, mutect2, varscan2
- EEF2 | c.1473G>A p.A491= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs1337575767, COSV58578869; called by muse, mutect2, varscan2
- EPG5 | c.5913A>G p.P1971= | Silent (SNP) | VAF 50/278 reads (18%) | catalogued as COSV56355149; called by muse, mutect2, varscan2
- ERAP2 | c.1695C>T p.R565= | Silent (SNP) | VAF 42/144 reads (29%) | catalogued as COSV65941165; called by muse, mutect2, varscan2
- FAT4 | c.1173C>T p.N391= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs776616142, COSV101271764, COSV67897987; called by muse, mutect2, varscan2
- FBXO43 | c.621T>C p.V207= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV71055295; called by muse, varscan2
- FBXW11 | c.225G>A p.L75= | Silent (SNP) | VAF 56/253 reads (22%) | catalogued as COSV51613288; called by muse, mutect2, varscan2
- GLUL | c.1038C>T p.C346= | Silent (SNP) | VAF 21/314 reads (7%) | catalogued as rs776531451, COSV59383174; called by muse, mutect2
- GMIP | c.2877G>A p.P959= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs768546077, COSV52559491; called by muse, mutect2, varscan2
- GPR149 | c.786G>A p.R262= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV67669527; called by muse, mutect2, varscan2
- GPR161 | c.1236G>A p.T412= | Silent (SNP) | VAF 46/512 reads (9%) | catalogued as rs764246824, COSV54793394; called by muse, mutect2
- GPT2 | c.915C>T p.N305= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as rs780818527, COSV60840062; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRM1 | c.3165C>T p.P1055= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1178140918, COSV51198312; called by muse, mutect2
- GTF3C3 | c.627T>C p.A209= | Silent (SNP) | VAF 110/460 reads (24%) | catalogued as COSV55834185; called by muse, mutect2, varscan2
- IGSF9 | c.1870C>T p.L624= (on ENST00000368094 / NM_001135050.2; = p.L608= on NM_020789.4) | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV63642047; called by muse, mutect2, varscan2
- INTS13 | c.1653A>G p.Q551= | Silent (SNP) | VAF 105/846 reads (12%) | catalogued as rs1241935420, COSV53905103; called by muse, mutect2, varscan2
- ITPR1 | c.4242C>T p.D1414= (on ENST00000354582; = p.D1399= on NM_002222.7) | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV57000890; called by muse, mutect2, varscan2
- KIF20A | c.2038T>C p.L680= | Silent (SNP) | VAF 23/121 reads (19%) | catalogued as COSV67510513; called by muse, mutect2, varscan2
- KRT5 | c.1128C>T p.G376= | Silent (SNP) | VAF 28/211 reads (13%) | catalogued as rs367665298, COSV52860238; called by muse, mutect2, varscan2
- LTBP1 | c.3375G>A p.Q1125= (on ENST00000404816 / NM_206943.4; = p.Q799= on NM_000627.4) | Silent (SNP) | VAF 82/361 reads (23%) | catalogued as COSV55384540; called by muse, mutect2, varscan2
- MAGI2 | c.2691C>T p.N897= | Silent (SNP) | VAF 7/203 reads (3%) | catalogued as COSV62692601; called by muse, mutect2
- MAN2B2 | c.702C>T p.G234= | Silent (SNP) | VAF 25/142 reads (18%) | catalogued as rs758694506, COSV53455795; called by muse, mutect2, varscan2
- MELTF | c.1671C>T p.R557= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs372026338; called by muse, mutect2, varscan2
- MMP15 | c.1713C>T p.D571= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs371936704, COSV99539768; called by muse, mutect2
- MPL | c.1857C>A p.T619= | Silent (SNP) | VAF 23/144 reads (16%) | catalogued as COSV65246838; called by muse, mutect2, varscan2
- MTTP | c.2124C>T p.N708= | Silent (SNP) | VAF 121/478 reads (25%) | catalogued as rs768562163, COSV55503488; called by muse, mutect2, varscan2
- MYO1F | c.402C>T p.G134= | Silent (SNP) | VAF 93/214 reads (43%) | catalogued as rs751538870, COSV57799539; called by muse, mutect2, varscan2
- NACC2 | c.1272C>T p.F424= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV53202566; called by muse, mutect2, varscan2
- NBEA | c.3378T>C p.N1126= | Silent (SNP) | VAF 91/334 reads (27%) | catalogued as COSV59816601; called by muse, mutect2, varscan2
- NDST1 | c.444C>T p.D148= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs373243938; ClinVar: likely benign; called by muse, mutect2, varscan2
- OLFML1 | c.789G>A p.Q263= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV55081614; called by muse, mutect2, varscan2
- OR2T2 | c.66T>C p.P22= | Silent (SNP) | VAF 70/1118 reads (6%) | catalogued as COSV61618886; called by muse, mutect2
- PABPC5 | c.762G>A p.K254= | Silent (SNP) | VAF 52/206 reads (25%) | catalogued as COSV57042945; called by muse, mutect2, varscan2
- PARN | c.1143C>T p.Y381= | Silent (SNP) | VAF 65/387 reads (17%) | catalogued as rs978508693, COSV58364978; called by muse, mutect2, varscan2
- PCDH1 | c.1494C>T p.D498= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs35082438; called by muse, mutect2, varscan2
- PCDHGB4 | c.15C>T p.A5= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV54018022; called by muse, mutect2, varscan2
- PCED1B | c.12G>A p.L4= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV71395598; called by muse, mutect2, varscan2
- PCSK2 | c.576C>T p.N192= | Silent (SNP) | VAF 89/331 reads (27%) | catalogued as rs775346093, COSV52741804; called by muse, mutect2, varscan2
- PEX6 | c.993C>T p.Y331= | Silent (SNP) | VAF 51/326 reads (16%) | catalogued as rs896144215, COSV55105171; called by muse, mutect2, varscan2
- PIAS4 | c.84C>T p.G28= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV53680901; called by muse, mutect2, varscan2
- PLAA | c.2175T>C p.C725= | Silent (SNP) | VAF 72/423 reads (17%) | catalogued as COSV68305507; called by muse, mutect2, varscan2
- PLP2 | c.294C>T p.T98= | Silent (SNP) | VAF 65/366 reads (18%) | catalogued as rs1212735208, COSV66240580; called by muse, mutect2, varscan2
- PMEPA1 | c.177G>A p.T59= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs533284164, COSV55696029, COSV99671852; called by muse, mutect2, varscan2
- PRDM14 | c.1704T>C p.H568= | Silent (SNP) | VAF 41/178 reads (23%) | catalogued as rs201853601, COSV52575059; called by muse, mutect2, varscan2
- PTPN21 | c.1614C>T p.S538= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs143395642; called by muse, mutect2
- PYGO2 | c.1101G>A p.G367= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as COSV63757570; called by muse, mutect2, varscan2
- RAB40C | c.399G>A p.K133= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV50195183; called by muse, mutect2
- RAB42 | c.37C>T p.L13= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1293302041, COSV65753236; called by muse, mutect2
- RAVER1 | c.825G>A p.A275= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs755219404, COSV53348334; called by muse, mutect2, varscan2
- RELT | c.177A>G p.A59= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV50362590; called by muse, mutect2, varscan2
- RIMBP2 | c.192C>T p.H64= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs372938466; called by muse, mutect2, varscan2
- RIPK4 | c.411G>A p.P137= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs775415877, COSV60190647; called by muse, mutect2, varscan2
- RNF113B | c.159C>T p.G53= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs1308416070, COSV57434134; called by muse, mutect2, varscan2
- RNF207 | c.1872C>T p.G624= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as rs779257537, COSV59472880; called by muse, mutect2
- ROBO3 | c.3075G>A p.A1025= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs776648534, COSV67302588; called by muse, mutect2, varscan2
- SACS | c.9738T>C p.N3246= | Silent (SNP) | VAF 70/464 reads (15%) | catalogued as COSV66545968; called by muse, mutect2, varscan2
- SATB2 | c.1455T>C p.A485= | Silent (SNP) | VAF 19/242 reads (8%) | catalogued as COSV53491465; called by muse, mutect2
- SLC16A11 | c.1113A>T p.G371= (on ENST00000308009; = p.G347= on NM_153357.3) | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs752693100, COSV57274951; called by muse, mutect2, varscan2
- SLC5A6 | c.54C>T p.S18= | Silent (SNP) | VAF 38/173 reads (22%) | catalogued as rs771351149, COSV60158389; called by muse, mutect2, varscan2
- SPATA20 | c.1851C>T p.G617= (on ENST00000356488 / NM_001258372.1; = p.G633= on NM_022827.4) | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs761090951, COSV50069638; called by muse, varscan2
- SSR2 | c.270C>T p.S90= | Silent (SNP) | VAF 63/460 reads (14%) | catalogued as COSV55304813; called by muse, mutect2, varscan2
- STH | c.81C>T p.C27= | Silent (SNP) | VAF 12/271 reads (4%) | catalogued as rs763740965, COSV52239658; called by muse, mutect2
- STK19 | c.126C>A p.A42= | Silent (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- STRA6 | c.1014C>T p.A338= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs1345912861, COSV60588191; called by muse, mutect2, varscan2
- TAF1L | c.4989T>G p.S1663= | Silent (SNP) | VAF 75/327 reads (23%) | catalogued as COSV54267852; called by muse, mutect2, varscan2
- TBXT | c.1218G>A p.A406= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs1157647187, COSV51619756; called by muse, mutect2
- THOP1 | c.1515G>A p.S505= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs371508092; called by mutect2, varscan2
- TNXB | c.312G>A p.R104= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV64487804; called by muse, mutect2, varscan2
- TOPORS | c.2535C>T p.D845= | Silent (SNP) | VAF 113/765 reads (15%) | catalogued as COSV62118023; called by muse, mutect2, varscan2
- TRPV5 | c.894C>A p.S298= | Silent (SNP) | VAF 11/146 reads (8%) | catalogued as COSV54689221; called by muse, mutect2
- TSSK1B | c.1068G>C p.G356= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as COSV66815985; called by muse, mutect2
- UGGT1 | c.885C>T p.P295= | Silent (SNP) | VAF 54/247 reads (22%) | catalogued as rs895536060, COSV52140791; called by muse, mutect2, varscan2
- USP20 | c.501G>A p.P167= | Silent (SNP) | VAF 39/133 reads (29%) | catalogued as rs965694772, COSV59611612; called by muse, mutect2, varscan2
- UTRN | c.8526T>C p.H2842= | Silent (SNP) | VAF 68/207 reads (33%) | catalogued as COSV62312333; called by muse, mutect2, varscan2
- WDR17 | c.1953C>T p.H651= | Silent (SNP) | VAF 58/253 reads (23%) | catalogued as rs142429080; called by muse, mutect2, varscan2
- ZMYM4 | c.66T>C p.F22= | Silent (SNP) | VAF 110/641 reads (17%) | catalogued as COSV58916338; called by muse, mutect2, varscan2
- ZNF383 | c.555T>C p.F185= | Silent (SNP) | VAF 29/154 reads (19%) | catalogued as rs1398421260, COSV61939973; called by muse, mutect2, varscan2
- ZNF556 | c.1281C>T p.C427= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as rs540339084, COSV56912008; called by muse, mutect2, varscan2
- C2orf83 | n.444T>C | RNA (SNP) | VAF 50/212 reads (24%) | catalogued as COSV52312651; called by muse, mutect2, varscan2
- CCDC144B | n.2326T>C | RNA (SNP) | VAF 180/1131 reads (16%) | catalogued as rs772371455; called by muse, mutect2, varscan2
- DENND10P1 | n.896C>T | RNA (SNP) | VAF 125/484 reads (26%) | called by muse, mutect2, varscan2
- GCK | c.46-5628C>A | Intron (SNP) | VAF 27/107 reads (25%) | catalogued as COSV61755293; called by muse, mutect2, varscan2
- MFSD12 | chr19:3542925 G>T | 3'Flank (SNP) | VAF 27/117 reads (23%) | catalogued as COSV61536658; called by muse, mutect2, varscan2
- MIR16-1 | n.2T>C | RNA (SNP) | VAF 22/352 reads (6%) | called by muse, mutect2
- POM121 | chr7:72949003 G>A | 3'Flank (SNP) | VAF 12/73 reads (16%) | catalogued as rs781966938, COSV57522935; called by muse, mutect2, varscan2
- SNX29P2 | n.471C>A | RNA (SNP) | VAF 65/527 reads (12%) | called by muse, mutect2, varscan2
- USH1C | c.1646+1124C>T | Intron (SNP) | VAF 31/124 reads (25%) | catalogued as rs767767573, COSV50032892; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
